Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAC9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAC9-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, hepatocellular 8170/3
Site Liver C22.0
p 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

1. Specimen: Liver: 7.0 x 8.5 x 5.0 cm, 93.5 g, unfixed
2. Tumor location: segment 8
Tumor number: one
Tumor size: 2.9 x 2.2 x 2.8 cm
3. Satellite nodule: no
4. Gross type
HCC: vaguely nodular
5. Tumor necrosis: no
6. Hemorrhage/peliosis: no
7. Portal vein invasion: no
8. Bile duct invasion: no

Gross photo present.

Blocks

T1-4, tumor mass x 4
RM, resection margin x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes
- 1-1. Differentiation
The worst differentiation II
The major differentiation II
- 1-2. Histologic type: trabecular, pseudoglandular
- 1-3. Cell type: hepatic
- 1-4. Fatty change: no
2. Cholangiocarcinoma: no
3. Combined hepatocellular and cholangiocarcinoma: no
4. Other tumor: no
5. Fibrous capsule formation: partial capsule
6. Capsular infiltration: yes
7. Septum formation: yes
8. Surgical resection margin invasion: no, margin of the clearance 0.5 cm
9. Serosal invasion: no
10. Portal vein invasion: no
11. Bile duct invasion: no

[page 2 of 2]
12. Hepatic vein invasion: no
13. Hepatic artery invasion: no
14. Microvessel invasion: no
15. Intrahepatic metastasis: no
16. Multicentric occurrence: no

Non-tumor liver pathology

1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: micronodular
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: no

SPECIAL STAIN: Trichrome (positive, stage 4)

Small intestine, duodenum, scopic, Chronic inflammation
stomach, antrum, scopic, chronic gastritis

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703

DIAGNOSIS:

Liver, segment 8, segmentectomy:
Hepatocellular carcinoma, moderately differentiated

Suggestion :

Source: NCI Genomic Data Commons file 42dfcedd-0d2e-4abb-aa55-e7d163b0ec1d (TCGA-DD-AAC9.A993CEA3-6AA2-4CE7-A9EC-8318B1377E99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).